Somatic mutation profile of tumor specimen C3L-02365-01 (aliquot CPT0114840009) from CPTAC case C3L-02365, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 62.8 years (22,934 days).
Specimen C3L-02365-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 554a34b8-9750-45e4-864b-2409207afcaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02365-31 (Blood Derived Normal), aliquot CPT0116900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a172a71-2b7b-420f-a044-c325a61b293b

The open-access MAF lists 486 somatic variants for this specimen: 335 protein-altering or splice-affecting, 89 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 89, Nonsense Mutation 24, Intron 23, RNA 13, Splice Site 12, 5'UTR 11, Frame Shift Del 10, 3'UTR 10, 5'Flank 4, Splice Region 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 224/490 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56896658; called by muse, mutect2
- ACTN2 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63976884; called by muse, mutect2, varscan2
- ANK3 | c.6843G>T p.Q2281H | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1398310479; called by muse, mutect2, varscan2
- ANXA2R | c.557G>C p.R186P | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as COSV59215027, COSV99043163; called by muse, mutect2, varscan2
- ANXA2R | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.859); catalogued as rs754645658, COSV100148644; called by muse, mutect2, varscan2
- APOB | c.7336G>A p.V2446M | Missense Mutation (SNP) | VAF 250/488 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs777259835; called by muse, mutect2, varscan2
- ARHGAP21 | c.3053G>A p.C1018Y | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as rs1227762637; called by muse, mutect2, varscan2
- ATP6V0A4 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 131/899 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs756026017; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.527del p.G176Efs*22 | Frame Shift Del (DEL) | VAF 55/144 reads (38%) | catalogued as COSV99958945; called by mutect2, pindel, varscan2
- C1QTNF3 | c.657G>C p.W219C | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV51468537; called by muse, mutect2, varscan2
- CACNA1H | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs898958342; called by muse, mutect2, varscan2
- CACNA2D2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs866928902; called by muse, mutect2, varscan2
- CAPN10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 169/273 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.26); catalogued as rs770374333; called by muse, mutect2, varscan2
- CCDC77 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV99519646; called by muse, varscan2
- CCNJL | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as rs747560990; called by muse, mutect2, varscan2
- CFAP54 | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs888582300; called by muse, mutect2, varscan2
- CHMP2B | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs1301607820; called by muse, mutect2, varscan2
- CHST5 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 165/351 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as COSV60339437; called by muse, mutect2, varscan2
- CPED1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 98/677 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV60013181; called by muse, mutect2, varscan2
- CPT1C | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764369739; called by muse, mutect2, varscan2
- CRACR2B | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs754975053; called by muse, mutect2, varscan2
- CSMD3 | c.8273C>G p.S2758C (on ENST00000297405 / NM_001363185.1; = p.S2589C on NM_052900.3) | Missense Mutation (SNP) | VAF 33/403 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99836941; called by muse, mutect2
- DDX43 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV64838019; called by muse, mutect2, varscan2
- DHX33 | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs769191375; called by muse, mutect2, varscan2
- DLST | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1243843561; called by muse, mutect2, varscan2
- DNAH6 | c.4954G>C p.V1652L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52875699; called by muse, mutect2, varscan2
- DPP10 | c.1951-1G>T p.X651_splice | Splice Site (SNP) | VAF 48/85 reads (56%) | catalogued as COSV59669368; called by muse, varscan2
- EDIL3 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 50/346 reads (14%) | catalogued as COSV56897678; called by muse, mutect2, varscan2
- EIF4A2 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV56216759; called by muse, mutect2, varscan2
- ELF3 | c.1083G>T p.W361C | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62839256; called by muse, mutect2, varscan2
- EMC1 | c.2488C>G p.L830V | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.192); catalogued as COSV64346356; called by muse, mutect2, varscan2
- EPHA5 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56653813, COSV56682709; called by muse, mutect2, varscan2
- F5 | c.5756C>G p.S1919C | Missense Mutation (SNP) | VAF 56/499 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV63129346; called by muse, mutect2, varscan2
- FASN | c.6127C>T p.R2043C | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60753830; called by muse, mutect2
- FAT3 | c.7114C>T p.P2372S | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1480609359, COSV99967827; called by muse, mutect2, varscan2
- FBXO42 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as COSV65045507; called by muse, mutect2, varscan2
- FECH | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as CS961589; called by muse, mutect2, varscan2
- FMN2 | c.2440C>A p.P814T | Missense Mutation (SNP) | VAF 132/334 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV60415581, COSV60420756; called by muse, mutect2, varscan2
- FMN2 | c.2797C>A p.P933T | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV100147114; called by muse, mutect2, varscan2
- GGH | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV52651150; called by muse, mutect2
- GPRASP1 | c.1967A>T p.H656L | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1423450472; called by muse, mutect2, varscan2
- H2AC20 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 274/778 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58613363; called by muse, mutect2, varscan2
- HTR3D | c.1226G>T p.R409L (on ENST00000382489 / NM_001163646.2; = p.R234L on NM_182537.3) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV100488126, COSV61913197; called by muse, mutect2, varscan2
- IGKV1D-33 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 96/339 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs1225070097; called by muse, varscan2
- INPPL1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 80/247 reads (32%) | catalogued as COSV53359359; called by muse, mutect2, varscan2
- INTS7 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV100877523; called by muse, mutect2, varscan2
- ITIH2 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV64431924; called by muse, varscan2
- KAT6A | c.5683C>T p.R1895C | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs773302173, COSV99705234; called by muse, mutect2, varscan2
- KEAP1 | c.1103G>T p.C368F | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50262195, COSV50263359; called by muse, mutect2, varscan2
- KIAA1671 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs973261086; called by muse, mutect2, varscan2
- KRT24 | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 26/165 reads (16%) | catalogued as COSV52879612; called by muse, mutect2, varscan2
- KRT33B | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 85/498 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52440191; called by muse, mutect2, varscan2
- LIPG | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 119/394 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99724732; called by muse, varscan2
- LMTK2 | c.3979G>T p.G1327* | Nonsense Mutation (SNP) | VAF 81/575 reads (14%) | catalogued as COSV51990078; called by muse, mutect2, varscan2
- LRRC69 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1377107260; called by muse, mutect2
- LRRK2 | c.7062C>G p.I2354M | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100108522; called by muse, varscan2
- LTBP2 | c.2596G>C p.D866H | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs148126707; called by muse, mutect2, varscan2
- LYST | c.2725G>T p.V909L | Missense Mutation (SNP) | VAF 186/560 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as rs146335682; called by muse, mutect2, varscan2
- MIA3 | c.2237A>T p.N746I | Missense Mutation (SNP) | VAF 146/303 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs767277066, COSV60510490; called by muse, mutect2, varscan2
- MYH4 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs201896271; called by muse, mutect2, varscan2
- NOBOX | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as rs1335967183, COSV56198352; called by muse, mutect2, varscan2
- NPY1R | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755519745; called by muse, mutect2, varscan2
- NTRK1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 159/333 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs141483265; called by muse, mutect2, varscan2
- NUP214 | c.3439A>T p.T1147S | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs878878224; called by muse, mutect2, varscan2
- NYX | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV61181686; called by muse, mutect2, varscan2
- OBSCN | c.16801-1G>T p.X5601_splice | Splice Site (SNP) | VAF 61/176 reads (35%) | catalogued as COSV99481195; called by muse, mutect2, varscan2
- OR10Q1 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104414483; called by muse, mutect2, varscan2
- OR1N2 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65461371; called by muse, mutect2, varscan2
- OR2M2 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 515/872 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV62898478; called by muse, mutect2, varscan2
- OR4M1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100270954, COSV60061572; called by muse, mutect2, varscan2
- OR52N2 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1564973892; called by muse, mutect2, varscan2
- OR6N2 | c.444T>G p.C148W | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755729492, COSV59411737; called by muse, mutect2, varscan2
- OR8I2 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV56168430; called by muse, mutect2, varscan2
- PCDHB3 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99164178; called by muse, mutect2, varscan2
- PHF6 | c.373A>C p.M125L | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1024978178; called by muse, mutect2, varscan2
- PKHD1L1 | c.2206G>T p.G736* | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as COSV65745026; called by muse, mutect2, varscan2
- PRKD1 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 40/174 reads (23%) | catalogued as COSV59564771; called by muse, varscan2
- PTCH1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs763774051; ClinVar: uncertain significance; called by muse, mutect2
- PTPN4 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779332065, COSV55299819; called by muse, mutect2, varscan2
- PTPRB | c.5195G>C p.R1732P | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99716851; called by muse, mutect2, varscan2
- PTPRE | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV54553084; called by muse, mutect2, varscan2
- PXDNL | c.3335G>T p.R1112L | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV62483120; called by muse, mutect2
- RIMS2 | c.1000C>G p.R334G (on ENST00000666250 / NM_001348490.2; = p.R142G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 276/501 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99166484; called by muse, mutect2, varscan2
- RIMS2 | c.3674G>C p.R1225T | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51737419; called by muse, mutect2, varscan2
- SAG | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 20/407 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.391); catalogued as rs201307508; ClinVar: uncertain significance; called by muse, mutect2
- SCN4B | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265062815, COSV61251899; called by muse, mutect2, varscan2
- SERPINA5 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752950539; called by muse, mutect2, varscan2
- SIPA1L3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756536229, COSV99730054; called by muse, mutect2, varscan2
- SLC43A2 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 133/289 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs953899951; called by muse, mutect2, varscan2
- SLC7A3 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1372449309, COSV53229797; called by muse, mutect2, varscan2
- SLIT3 | c.1608C>A p.D536E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV60597142; called by muse, varscan2
- SPATA16 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100651600, COSV63533252; called by muse, mutect2
- SPATA17 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100861212; called by muse, mutect2
- SPRED2 | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 117/195 reads (60%) | catalogued as COSV62692711; called by muse, mutect2, varscan2
- SPTA1 | c.2124G>T p.W708C | Missense Mutation (SNP) | VAF 62/591 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV63752767; called by muse, mutect2, varscan2
- SPTBN4 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs956153403; called by muse, mutect2, varscan2
- SSRP1 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV53481062; called by muse, mutect2, varscan2
- STON2 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as COSV50860403; called by muse, varscan2
- TLE6 | c.709C>T p.P237S (on ENST00000246112 / NM_001143986.2; = p.P114S on NM_024760.3) | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV55736910, COSV99857829; called by muse, mutect2, varscan2
- TMEM117 | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as COSV99075258; called by muse, mutect2, varscan2
- TRRAP | c.6629G>A p.R2210Q (on ENST00000359863 / NM_001244580.1; = p.R2192Q on NM_003496.3) | Missense Mutation (SNP) | VAF 58/507 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1461946712; called by muse, mutect2, varscan2
- TTN | c.13336C>A p.Q4446K (on ENST00000591111; = p.Q4400K on NM_003319.4) | Missense Mutation (SNP) | VAF 190/318 reads (60%) | PolyPhen benign (0.236); catalogued as rs1187967109; called by muse, mutect2, varscan2
- USH2A | c.2348A>C p.N783T | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV56327866, COSV56347503; called by muse, mutect2
- VPS52 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 78/157 reads (50%) | catalogued as COSV99067754; called by muse, mutect2, varscan2
- ZFC3H1 | c.2600A>T p.K867M | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66432170; called by muse, mutect2, varscan2
- ZFHX4 | c.6130C>A p.P2044T | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1389108202; called by muse, mutect2
- ZNF518B | c.2971C>A p.R991S | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100456712; called by muse, mutect2, varscan2
- ZNF683 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV62875662; called by muse, mutect2, varscan2
- ZNF735 | c.568T>C p.Y190H | Missense Mutation (SNP) | VAF 147/262 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV70034243; called by muse, mutect2, varscan2
- ZNF853 | c.1677C>A p.H559Q | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71922854; called by muse, mutect2, varscan2
- ABCA10 | c.4478-1G>T p.X1493_splice | Splice Site (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- ABCB1 | c.3160C>A p.Q1054K | Missense Mutation (SNP) | VAF 256/511 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ABCC2 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ABCC2 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AC011005.1 | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 412/833 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ACADM | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ACOT12 | c.689T>A p.V230E | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADAMTS7 | c.2358G>T p.K786N | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1031G>T p.R344I | Missense Mutation (SNP) | VAF 196/376 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY1 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ADGRE1 | c.2455G>T p.G819* | Nonsense Mutation (SNP) | VAF 49/140 reads (35%) | called by muse, mutect2, varscan2
- AFF2 | c.2521G>A p.V841I | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AGTR1 | c.919A>C p.K307Q | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2
- AIFM3 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AKAP9 | c.2966A>C p.Q989P | Missense Mutation (SNP) | VAF 115/211 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ALDH9A1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ALG10 | c.853dup p.C285Lfs*26 | Frame Shift Ins (INS) | VAF 64/273 reads (23%) | called by mutect2, varscan2
- AMER1 | c.2229G>C p.R743S | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- AP3B1 | c.2488C>G p.P830A | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- APOOL | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ARFGEF3 | c.4105_4109del p.D1369* | Frame Shift Del (DEL) | VAF 38/157 reads (24%) | called by mutect2, pindel, varscan2
- ATG14 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 147/463 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- B2M | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 86/251 reads (34%) | called by muse, mutect2, varscan2
- BICRA | c.3864del p.M1289Cfs*71 | Frame Shift Del (DEL) | VAF 108/530 reads (20%) | called by pindel, varscan2
- BTBD11 | c.938G>C p.C313S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- C10orf67 | c.194_206+6del p.X65_splice (on ENST00000323327; = p.X66_splice on NM_153714.3) | Splice Site (DEL) | VAF 115/281 reads (41%) | called by mutect2, pindel, varscan2
- C1orf35 | c.292-3C>A | Splice Region (SNP) | VAF 66/370 reads (18%) | called by muse, mutect2, varscan2
- C20orf194 | c.1813A>G p.I605V | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf54 | c.1981T>A p.W661R | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACHD1 | c.1562C>G p.S521C | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1B | c.1821G>T p.K607N | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1E | c.3046G>C p.G1016R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CADPS2 | c.1163G>C p.C388S | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CAMK2B | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 52/791 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC160 | c.120C>G p.S40R | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC186 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CDH23 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.087); called by muse, varscan2
- CDON | c.3778G>T p.G1260C (on ENST00000392693 / NM_001243597.2; = p.G1237C on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CECR2 | c.832G>T p.D278Y (on ENST00000342247 / NM_001290047.2; = p.D115Y on NM_001290046.1) | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CENATAC | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CES5A | c.73+2T>C p.X25_splice | Splice Site (SNP) | VAF 49/314 reads (16%) | called by muse, mutect2, varscan2
- CFAP47 | c.6935T>A p.I2312N | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2
- CFAP69 | c.2189-5T>A | Splice Region (SNP) | VAF 30/291 reads (10%) | called by muse, mutect2, varscan2
- CKAP5 | c.4418A>T p.H1473L | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CLCA2 | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CLDN17 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CNTN4 | c.2380G>C p.V794L | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- COBLL1 | c.3200C>T p.A1067V (on ENST00000392717; = p.A1029V on NM_014900.5) | Missense Mutation (SNP) | VAF 19/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL4A2 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COL5A2 | c.2500-2A>T p.X834_splice | Splice Site (SNP) | VAF 269/438 reads (61%) | called by muse, mutect2, varscan2
- CORIN | c.2431G>T p.G811* | Nonsense Mutation (SNP) | VAF 54/310 reads (17%) | called by muse, mutect2, varscan2
- CPNE7 | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 146/319 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CRIM1 | c.2624-1G>C p.X875_splice | Splice Site (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- CSMD2 | c.5574C>G p.N1858K | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CSMD3 | c.9210C>A p.S3070R (on ENST00000297405 / NM_001363185.1; = p.S2901R on NM_052900.3) | Missense Mutation (SNP) | VAF 212/774 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CTAGE9 | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 58/1085 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CTU1 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DCAF13 | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 30/403 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DDI1 | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DLL1 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- DMBX1 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.7729C>A p.L2577M | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.10428G>C p.K3476N | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH9 | c.5973-1G>T p.X1991_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EDIL3 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMOD1 | c.832T>A p.C278S | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- EPHB1 | c.584A>T p.K195M | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ESPNL | c.2293A>G p.T765A | Missense Mutation (SNP) | VAF 148/239 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ESR1 | c.923dup p.L308Ffs*16 | Frame Shift Ins (INS) | VAF 171/467 reads (37%) | called by mutect2, pindel, varscan2
- EXOC3L1 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EZH2 | c.2224G>C p.E742Q (on ENST00000460911 / NM_001203247.2; = p.E747Q on NM_004456.5) | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- F5 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 49/557 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- FADS6 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.13522C>A p.P4508T | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXL7 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO17 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- FGF23 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFR1 | c.1064G>T p.W355L (on ENST00000447712 / NM_023110.3; = p.W353L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FLT3 | c.1655T>C p.L552P | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOLR1 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 86/577 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- FREM3 | c.1748T>G p.L583R | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FREM3 | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GIMAP6 | c.150del p.S51Vfs*25 | Frame Shift Del (DEL) | VAF 133/376 reads (35%) | called by mutect2, pindel, varscan2
- GJA1 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 100/608 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- GJA8 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 45/398 reads (11%) | called by muse, mutect2, varscan2
- GJB4 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 148/535 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- GLUD2 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 170/434 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOT1 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPHN | c.1324G>A p.E442K (on ENST00000315266 / NM_001377519.1; = p.E475K on NM_020806.5) | Missense Mutation (SNP) | VAF 50/469 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GPR174 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.068); called by muse, mutect2
- GRIA2 | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GSG1 | c.657C>A p.H219Q (on ENST00000651961 / NM_001080555.4; = p.H225N on NM_031289.5) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- GSS | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 91/497 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTSF1L | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H2BW1 | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HCN1 | c.2126A>T p.Q709L | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); called by muse, mutect2
- HEPH | c.2095T>G p.C699G (on ENST00000343002; = p.C432G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC4 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, varscan2
- HOXA10 | c.772T>A p.S258T | Missense Mutation (SNP) | VAF 100/169 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGLV3-12 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 39/641 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- INKA2 | c.613G>C p.A205P | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IQCA1 | c.1934_1935del p.K645Sfs*9 | Frame Shift Del (DEL) | VAF 63/258 reads (24%) | called by mutect2, pindel, varscan2
- IQGAP3 | c.4396C>A p.L1466M | Missense Mutation (SNP) | VAF 130/258 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- IRX3 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ITGAV | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 123/236 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPKB | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.8881C>A p.R2961S (on ENST00000360013 / NM_001024660.4; = p.R1264S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNH5 | c.470C>G p.T157R | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- KIF18A | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- KLHL32 | c.821A>T p.Q274L | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- KMT2E | c.2909A>T p.Y970F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KPNA5 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- KRT79 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- KSR2 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA1 | c.8110G>C p.D2704H | Missense Mutation (SNP) | VAF 93/457 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- LIPM | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- LRIG3 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRP1B | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 109/193 reads (56%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRC4C | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- LRRC63 | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MACF1 | c.21043G>T p.E7015* (on ENST00000372915; = p.E5060* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
- MAP1S | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MAP2 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, varscan2
- MARCHF6 | c.1757A>C p.N586T | Missense Mutation (SNP) | VAF 28/587 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- MBNL3 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP8 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRC1 | c.2053G>T p.G685* | Nonsense Mutation (SNP) | VAF 171/395 reads (43%) | called by muse, mutect2, varscan2
- MSMB | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- MSMB | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MTMR4 | c.3251T>C p.F1084S | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC16 | c.41683T>C p.Y13895H | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MUC22 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MYO3B | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MYOG | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEB | c.14443C>A p.L4815M | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NETO1 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIPBL | c.3533A>T p.Q1178L | Missense Mutation (SNP) | VAF 92/549 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- NIPBL | c.7465G>C p.E2489Q | Missense Mutation (SNP) | VAF 37/389 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- NIT1 | c.86G>C p.C29S | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP3 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 152/1542 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- NPAS3 | c.1566C>A p.N522K (on ENST00000356141 / NM_001164749.2; = p.N490K on NM_022123.3) | Missense Mutation (SNP) | VAF 86/607 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- NPHP4 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NSRP1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- NYNRIN | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- OR10Q1 | c.873C>A p.N291K | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10R2 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR2T1 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR51S1 | c.164G>A p.W55* | Nonsense Mutation (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- OR5F1 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6N1 | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- OR8J3 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OXA1L | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 68/488 reads (14%) | called by muse, mutect2, varscan2
- P2RX6 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 47/454 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PAK3 | c.926T>A p.V309E (on ENST00000262836 / NM_001324328.2; = p.V294E on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAK5 | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2
- PCDHA2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PCDHA5 | c.1052T>A p.I351K | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PCDHB3 | c.2227G>T p.G743W | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA3 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PCDHGA5 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PCLO | c.3251A>C p.N1084T | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.036); called by muse, mutect2
- PDHB | c.724del p.H242Ifs*9 | Frame Shift Del (DEL) | VAF 64/370 reads (17%) | called by mutect2, pindel, varscan2
- PDSS1 | c.228G>T p.R76= | Splice Region (SNP) | VAF 126/369 reads (34%) | called by muse, varscan2
- PKHD1 | c.4610dup p.C1538Vfs*27 | Frame Shift Ins (INS) | VAF 221/539 reads (41%) | called by mutect2, pindel, varscan2
- POU4F1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPRC1 | c.4271G>T p.G1424V | Missense Mutation (SNP) | VAF 69/357 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- PRPS1L1 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 148/281 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PRRC2B | c.294-1G>T p.X98_splice | Splice Site (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2395G>T p.D799Y | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRQ | c.221T>A p.I74K (on ENST00000616559; = p.I32K on NM_001145026.2) | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PXDNL | c.2151C>A p.N717K | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2
- QSOX2 | c.2055G>T p.R685S | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- RAB11FIP5 | c.793T>G p.L265V | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RADIL | c.2562G>T p.R854S | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RADIL | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF122 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- RSPH14 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 182/393 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SAMD7 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SETBP1 | c.4461del p.K1488Sfs*4 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel
- SGIP1 | c.1951A>C p.N651H | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- SIX1 | c.177C>A p.H59Q | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLC4A8 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A9 | c.2536T>C p.Y846H (on ENST00000507527 / NM_001258428.2; = p.Y822H on NM_031467.3) | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC6A15 | c.439A>T p.S147C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX3 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SOBP | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SOX14 | c.533del p.G178Afs*47 | Frame Shift Del (DEL) | VAF 40/191 reads (21%) | called by mutect2, pindel, varscan2
- SPTA1 | c.2123G>T p.W708L | Missense Mutation (SNP) | VAF 64/603 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- ST6GAL2 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 29/231 reads (13%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STK32C | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SUSD3 | c.425+1G>T p.X142_splice | Splice Site (SNP) | VAF 36/188 reads (19%) | called by muse, mutect2
- TBC1D25 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 14/504 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2
- TBC1D31 | c.729G>T p.L243F | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- TBC1D31 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- TDGF1 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 171/420 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- TIAM1 | c.2830G>A p.V944M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, varscan2
- TIAM1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 64/385 reads (17%) | called by muse, mutect2, varscan2
- TMC1 | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 110/653 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM71 | c.282C>G p.N94K | Missense Mutation (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- TNNI1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TPP2 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAJ54 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.62C>G p.T21S | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM15 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 130/247 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRIP6 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- UNC13C | c.1207G>T p.G403* | Nonsense Mutation (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- UNC13C | c.3150+1G>T p.X1050_splice | Splice Site (SNP) | VAF 84/203 reads (41%) | called by muse, mutect2, varscan2
- USF3 | c.1913C>A p.P638Q | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCAN | c.4932_4933delinsC p.E1644Dfs*13 | Frame Shift Del (DEL) | VAF 56/269 reads (21%) | called by pindel, varscan2*
- VGLL1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- WASHC5 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 26/581 reads (4%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.989); called by muse, mutect2
- WDR47 | c.536_539del p.D179Gfs*3 | Frame Shift Del (DEL) | VAF 151/309 reads (49%) | called by mutect2, pindel, varscan2
- WWC3 | c.2033C>A p.S678Y | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- XDH | c.3022A>T p.I1008L | Missense Mutation (SNP) | VAF 168/363 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ZNF264 | c.34-2A>T p.X12_splice | Splice Site (SNP) | VAF 65/119 reads (55%) | called by muse, mutect2, varscan2
- ZNF460 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF543 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ZNF594 | c.795A>C p.K265N | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF711 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ZNF716 | c.37A>T p.M13L | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, mutect2
- ZNF785 | c.767A>T p.Y256F | Missense Mutation (SNP) | VAF 110/494 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ZNF860 | c.1766T>A p.M589K | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNRF3 | c.1873G>T p.E625* (on ENST00000544604 / NM_001206998.2; = p.E525* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- AC138647.1 | c.177C>G p.R59= | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as COSV70194774; called by muse, mutect2
- ACIN1 | c.339A>G p.K113= | Silent (SNP) | VAF 65/327 reads (20%) | called by muse, mutect2, varscan2
- ACTN2 | c.564C>A p.A188= | Silent (SNP) | VAF 52/451 reads (12%) | called by mutect2, varscan2
- ADCY8 | c.711C>A p.T237= | Silent (SNP) | VAF 151/552 reads (27%) | called by muse, mutect2, varscan2
- ARMH4 | c.1056T>C p.G352= | Silent (SNP) | VAF 31/211 reads (15%) | called by muse, mutect2, varscan2
- BEND3 | c.1563G>T p.R521= | Silent (SNP) | VAF 81/278 reads (29%) | called by muse, mutect2, varscan2
- BEST2 | c.1386C>G p.A462= | Silent (SNP) | VAF 131/517 reads (25%) | called by muse, mutect2, varscan2
- C19orf18 | c.435G>C p.P145= | Silent (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- C9 | c.237C>T p.T79= | Silent (SNP) | VAF 106/701 reads (15%) | catalogued as rs754596142; called by muse, mutect2, varscan2
- CCDC168 | c.10347C>T p.S3449= | Silent (SNP) | VAF 73/291 reads (25%) | catalogued as rs1209316600; called by muse, mutect2, varscan2
- CCDC183 | c.1536C>T p.A512= | Silent (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- CELSR2 | c.3477G>A p.T1159= | Silent (SNP) | VAF 116/233 reads (50%) | catalogued as rs768656316, COSV54778997; called by muse, mutect2, varscan2
- CNTLN | c.3675C>G p.L1225= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as rs1414301431; called by muse, mutect2, varscan2
- CNTN5 | c.237C>A p.P79= | Silent (SNP) | VAF 90/400 reads (23%) | catalogued as rs753301950, COSV54305973; called by muse, mutect2, varscan2
- COL22A1 | c.588C>T p.H196= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as rs1167546280, COSV57346244; called by muse, mutect2
- CSTF1 | c.1173G>C p.L391= | Silent (SNP) | VAF 77/492 reads (16%) | catalogued as rs565546367; called by muse, mutect2, varscan2
- CSTF1 | c.1174C>T p.L392= | Silent (SNP) | VAF 78/490 reads (16%) | called by muse, mutect2, varscan2
- CTCFL | c.486G>T p.V162= | Silent (SNP) | VAF 129/271 reads (48%) | called by muse, mutect2, varscan2
- DHX16 | c.2199G>A p.K733= | Silent (SNP) | VAF 48/249 reads (19%) | called by muse, mutect2, varscan2
- DMBX1 | c.930C>A p.A310= | Silent (SNP) | VAF 42/329 reads (13%) | called by muse, mutect2, varscan2
- DST | c.6609T>C p.N2203= | Silent (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- FAM13C | c.1728C>A p.I576= | Silent (SNP) | VAF 64/254 reads (25%) | called by muse, mutect2, varscan2
- FAT3 | c.6114T>C p.T2038= | Silent (SNP) | VAF 18/258 reads (7%) | catalogued as rs1360678371; called by muse, mutect2
- FRMPD1 | c.4185G>A p.R1395= | Silent (SNP) | VAF 70/217 reads (32%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.72G>C p.L24= | Silent (SNP) | VAF 280/480 reads (58%) | catalogued as rs779519669; called by muse, mutect2, varscan2
- GRID2IP | c.1839G>T p.P613= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs377425738; called by muse, mutect2, varscan2
- HS3ST3A1 | c.438C>T p.D146= | Silent (SNP) | VAF 44/215 reads (20%) | called by muse, mutect2, varscan2
- IGSF1 | c.3948C>A p.T1316= | Silent (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- ITGAM | c.36C>A p.T12= | Silent (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- JAG2 | c.1923G>T p.L641= | Silent (SNP) | VAF 262/747 reads (35%) | called by muse, mutect2, varscan2
- JARID2 | c.153C>T p.G51= | Silent (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- KCNN2 | c.1653C>T p.V551= (on ENST00000264773; = p.V763= on NM_021614.4) | Silent (SNP) | VAF 40/287 reads (14%) | called by muse, mutect2, varscan2
- KIF5A | c.531G>A p.P177= | Silent (SNP) | VAF 72/377 reads (19%) | catalogued as rs771476833, COSV54052915; ClinVar: benign; called by muse, mutect2, varscan2
- KRTAP5-11 | c.33C>T p.G11= | Silent (SNP) | VAF 50/311 reads (16%) | called by muse, mutect2, varscan2
- LRP1B | c.4521G>A p.Q1507= | Silent (SNP) | VAF 9/225 reads (4%) | catalogued as COSV101254041; called by muse, mutect2
- LRRC4C | c.123G>A p.L41= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as COSV99537515; called by muse, mutect2, varscan2
- LRRC53 | c.627G>A p.L209= | Silent (SNP) | VAF 46/329 reads (14%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1185G>T p.A395= | Silent (SNP) | VAF 81/169 reads (48%) | catalogued as COSV54437756; called by muse, mutect2, varscan2
- LY6H | c.102C>G p.T34= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- MINDY4 | c.1482C>T p.C494= | Silent (SNP) | VAF 55/424 reads (13%) | catalogued as rs1212182420, COSV99519486; called by muse, mutect2, varscan2
- MOGAT1 | c.546T>A p.S182= | Silent (SNP) | VAF 148/252 reads (59%) | called by muse, mutect2, varscan2
- MTNR1B | c.111C>A p.P37= | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- MYOM3 | c.2883C>A p.P961= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as COSV58397370; called by muse, mutect2, varscan2
- NARF | c.294G>C p.V98= | Silent (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
- NCKAP5L | c.1830A>G p.P610= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- NDST4 | c.687C>A p.T229= | Silent (SNP) | VAF 53/237 reads (22%) | called by muse, mutect2, varscan2
- NEXN | c.1548A>G p.R516= | Silent (SNP) | VAF 117/392 reads (30%) | called by muse, mutect2, varscan2
- NOTCH2 | c.3804C>T p.C1268= | Silent (SNP) | VAF 90/685 reads (13%) | called by muse, mutect2, varscan2
- NR1H4 | c.102C>G p.P34= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99500194; called by muse, mutect2, varscan2
- NSD1 | c.4137G>T p.P1379= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV61785464; called by muse, mutect2, varscan2
- OR2T2 | c.324G>T p.L108= | Silent (SNP) | VAF 105/2000 reads (5%) | catalogued as COSV61619372; called by muse, mutect2
- OR52A5 | c.138A>T p.L46= | Silent (SNP) | VAF 43/168 reads (26%) | called by muse, mutect2, varscan2
- OR52N4 | c.468A>G p.L156= | Silent (SNP) | VAF 14/343 reads (4%) | called by muse, mutect2
- OR5A1 | c.48C>T p.I16= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV57376578; called by muse, mutect2
- OR6N1 | c.390C>A p.L130= | Silent (SNP) | VAF 36/278 reads (13%) | called by muse, mutect2, varscan2
- OS9 | c.750A>G p.L250= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV57783003; called by muse, mutect2, varscan2
- PAPPA2 | c.4350T>A p.S1450= | Silent (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- PHLPP1 | c.300G>A p.Q100= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- PHTF1 | c.1608A>G p.E536= | Silent (SNP) | VAF 79/248 reads (32%) | called by muse, mutect2, varscan2
- PIPOX | c.711T>C p.Y237= | Silent (SNP) | VAF 48/269 reads (18%) | called by muse, mutect2, varscan2
- PLCL1 | c.3021T>C p.H1007= | Silent (SNP) | VAF 95/166 reads (57%) | called by muse, mutect2, varscan2
- PPP2R5C | c.1311C>T p.A437= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs765987468; called by muse, mutect2, varscan2
- PRSS23 | c.915C>G p.L305= | Silent (SNP) | VAF 77/388 reads (20%) | called by muse, mutect2, varscan2
- PTPN12 | c.966C>T p.V322= | Silent (SNP) | VAF 36/293 reads (12%) | called by muse, mutect2, varscan2
- PTPRB | c.5196A>G p.R1732= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.561T>C p.T187= | Silent (SNP) | VAF 51/466 reads (11%) | called by muse, mutect2, varscan2
- RPF2 | c.786T>A p.T262= | Silent (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- SALL1 | c.1575C>T p.G525= | Silent (SNP) | VAF 41/193 reads (21%) | called by muse, mutect2, varscan2
- SEC23A | c.2004G>A p.R668= | Silent (SNP) | VAF 74/287 reads (26%) | called by muse, varscan2
- SERPINC1 | c.1053C>T p.H351= | Silent (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- SIX3 | c.984G>A p.S328= | Silent (SNP) | VAF 88/569 reads (15%) | catalogued as rs1232352852; called by muse, mutect2, varscan2
- SLC6A1 | c.1644C>T p.I548= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as rs200481115, COSV55119114; called by muse, mutect2, varscan2
- SPNS1 | c.1545G>T p.R515= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- SPTA1 | c.4815G>A p.E1605= | Silent (SNP) | VAF 93/772 reads (12%) | catalogued as rs891508747; called by muse, mutect2, varscan2
- SSTR4 | c.447G>T p.V149= | Silent (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- SV2C | c.1317T>A p.V439= | Silent (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- SYNE2 | c.18834C>T p.D6278= | Silent (SNP) | VAF 80/580 reads (14%) | catalogued as rs757742735; called by muse, mutect2, varscan2
- TESC | c.321G>T p.V107= | Silent (SNP) | VAF 41/209 reads (20%) | called by muse, mutect2, varscan2
- TMEM218 | c.66G>T p.V22= | Silent (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- TNF | c.459C>A p.T153= | Silent (SNP) | VAF 190/395 reads (48%) | called by muse, mutect2, varscan2
- TPBGL | c.477G>T p.A159= | Silent (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- TRAV30 | c.108G>T p.G36= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- TRBV29-1 | c.246C>A p.P82= | Silent (SNP) | VAF 57/416 reads (14%) | called by muse, mutect2, varscan2
- TRPC5 | c.402G>A p.T134= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1181661291, COSV99461797; called by muse, mutect2, varscan2
- TUBA3E | c.57C>A p.A19= | Silent (SNP) | VAF 136/255 reads (53%) | called by muse, mutect2, varscan2
- TUT7 | c.2970G>T p.L990= | Silent (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- WDR4 | c.615G>C p.L205= | Silent (SNP) | VAF 42/278 reads (15%) | catalogued as rs1252865410; called by muse, mutect2, varscan2
- ZNF16 | c.561C>A p.G187= | Silent (SNP) | VAF 20/410 reads (5%) | called by muse, mutect2
- ZNF804B | c.354G>T p.L118= | Silent (SNP) | VAF 175/382 reads (46%) | catalogued as rs1242060780; called by muse, mutect2, varscan2
- ABCA3 | c.*322G>T | 3'UTR (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- AC025048.6 | n.540G>A | RNA (SNP) | VAF 79/414 reads (19%) | catalogued as rs1317757971; called by muse, mutect2, varscan2
- AL450442.1 | n.762G>T | RNA (SNP) | VAF 33/307 reads (11%) | called by muse, mutect2, varscan2
- COX7C | c.*32G>A | 3'UTR (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- CPEB1-AS1 | chr15:82647784 G>A | 5'Flank (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CPNE6 | c.-120+25G>C | Intron (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- CTSLP8 | n.626C>A | RNA (SNP) | VAF 44/254 reads (17%) | catalogued as rs1457973747; called by muse, mutect2, varscan2
- DAZL | c.-39C>A | 5'UTR (SNP) | VAF 52/284 reads (18%) | catalogued as COSV99167447; called by muse, mutect2, varscan2
- DENND2B | c.-25-6370C>T | Intron (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- ELN | c.377-25T>A | Intron (SNP) | VAF 613/1227 reads (50%) | called by muse, mutect2, varscan2
- EYS | c.1767-6532G>T | Intron (SNP) | VAF 25/198 reads (13%) | called by mutect2, varscan2
- FAM205BP | n.1946C>T | RNA (SNP) | VAF 80/615 reads (13%) | catalogued as rs779447299; called by muse, mutect2, varscan2
- FAT1 | c.13139-1430T>C | Intron (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- FGF14 | c.-25G>A | 5'UTR (SNP) | VAF 80/220 reads (36%) | called by muse, mutect2, varscan2
- GABRB1 | c.-10A>T | 5'UTR (SNP) | VAF 20/170 reads (12%) | called by muse, varscan2
- GABRG2 | c.1042+26G>A | Intron (SNP) | VAF 18/250 reads (7%) | catalogued as rs760110295; called by muse, mutect2
- GAR1 | c.*39_*41dup | 3'UTR (INS) | VAF 66/139 reads (47%) | called by mutect2, pindel, varscan2
- GNG2 | c.-25C>A | 5'UTR (SNP) | VAF 83/184 reads (45%) | called by muse, varscan2
- GPATCH8 | c.*880A>T | 3'UTR (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-2134A>C | Intron (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- HMGB1P1 | n.447G>A | RNA (SNP) | VAF 33/550 reads (6%) | catalogued as rs766927146; called by muse, mutect2
- HPS5 | c.1511-46del | Intron (DEL) | VAF 58/204 reads (28%) | called by mutect2, pindel
- HSP90AB3P | n.346G>T | RNA (SNP) | VAF 102/219 reads (47%) | catalogued as rs777371945; called by muse, mutect2, varscan2
- IGLV2-14 | c.-12G>T | 5'UTR (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2
- ITGA4 | c.*2580C>A | 3'UTR (SNP) | VAF 84/137 reads (61%) | called by muse, mutect2, varscan2
- ITPR2 | c.-26A>G | 5'UTR (SNP) | VAF 63/349 reads (18%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.129C>A | RNA (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- LAS1L | c.846+30C>G | Intron (SNP) | VAF 86/251 reads (34%) | called by muse, mutect2, varscan2
- LGI3 | chr8:22159766 del C | 5'Flank (DEL) | VAF 79/320 reads (25%) | catalogued as rs1160714931; called by mutect2, pindel, varscan2
- MCCC2 | c.999+866C>T | Intron (SNP) | VAF 9/59 reads (15%) | catalogued as rs1201669085; called by muse, mutect2, varscan2
- MIR31 | n.63C>T | RNA (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NAA40 | c.-81C>T | 5'UTR (SNP) | VAF 53/223 reads (24%) | catalogued as rs949664505; called by muse, mutect2, varscan2
- NUB1 | c.1467+90C>T | Intron (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- OAS3 | c.636+33G>T | Intron (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2
- PABPC1P2 | n.1175C>A | RNA (SNP) | VAF 372/630 reads (59%) | called by muse, mutect2, varscan2
- PFKFB3 | c.-17C>G | 5'UTR (SNP) | VAF 56/409 reads (14%) | called by muse, mutect2, varscan2
- PLN | c.-17C>A | 5'UTR (SNP) | VAF 111/290 reads (38%) | called by muse, mutect2, varscan2
- PNPLA7 | c.1151-3637C>T | Intron (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- POU4F3 | c.*35C>G | 3'UTR (SNP) | VAF 49/269 reads (18%) | called by muse, mutect2, varscan2
- RBM28 | c.*43T>C | 3'UTR (SNP) | VAF 139/468 reads (30%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-13A>T | Intron (SNP) | VAF 159/252 reads (63%) | called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809912 G>T | 5'Flank (SNP) | VAF 198/364 reads (54%) | called by muse, mutect2, varscan2
- SDHA | chr5:218281 C>A | 5'Flank (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- SEC23A | c.1987-43G>T | Intron (SNP) | VAF 49/136 reads (36%) | called by muse, varscan2
- SEMA3G | c.116-127A>T | Intron (SNP) | VAF 63/196 reads (32%) | called by muse, mutect2, varscan2
- SEMA4D | chr9:89376958 G>A | 3'Flank (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- SERPINA13P | n.501C>T | RNA (SNP) | VAF 30/213 reads (14%) | catalogued as rs774453759; called by muse, mutect2, varscan2
- SHMT2 | c.-61C>T | 5'UTR (SNP) | VAF 36/191 reads (19%) | catalogued as rs780826184; called by muse, mutect2, varscan2
- SLC1A3 | c.181+4263T>C | Intron (SNP) | VAF 34/354 reads (10%) | called by muse, mutect2
- SSPOP | n.11343C>A | RNA (SNP) | VAF 87/178 reads (49%) | catalogued as rs1410432661; called by muse, mutect2, varscan2
- ST13P4 | n.78G>A | RNA (SNP) | VAF 93/312 reads (30%) | called by muse, mutect2, varscan2
- ST13P4 | n.79G>A | RNA (SNP) | VAF 94/314 reads (30%) | catalogued as rs1348594744; called by muse, mutect2, varscan2
- STXBP1 | c.1702+1846G>C | Intron (SNP) | VAF 63/360 reads (18%) | called by muse, mutect2, varscan2
- TBX1 | c.1009+501G>T | Intron (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- TCF7L2 | c.552+49344G>T | Intron (SNP) | VAF 43/206 reads (21%) | catalogued as COSV60504768; called by muse, mutect2, varscan2
- THY1 | c.*53C>A | 3'UTR (SNP) | VAF 86/285 reads (30%) | catalogued as rs745405381; called by muse, mutect2, varscan2
- TNFRSF10B | c.*1387C>G | 3'UTR (SNP) | VAF 116/402 reads (29%) | called by muse, mutect2, varscan2
- TSEN54 | c.369+35del | Intron (DEL) | VAF 53/282 reads (19%) | called by mutect2, pindel, varscan2
- TTC31 | c.129+169G>A | Intron (SNP) | VAF 30/51 reads (59%) | catalogued as rs1187011660; called by muse, varscan2
- VSTM2B | c.-39G>A | 5'UTR (SNP) | VAF 87/204 reads (43%) | called by muse, mutect2, varscan2
- ZBP1 | c.*162G>T | 3'UTR (SNP) | VAF 108/272 reads (40%) | called by muse, mutect2, varscan2
- ZEB2 | c.332-40T>A | Intron (SNP) | VAF 140/250 reads (56%) | called by muse, mutect2, varscan2
